TCGA case TCGA-78-7633 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Prince Charles Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/44218b35-219c-4ad9-a01e-fde14067c4c0

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: Australia; Age at index: 67 years; Vital status: Dead; Days to death: 1,528 days (4.2 years).

Diagnoses (3)
1. Adenocarcinoma with mixed subtypes (the primary disease): ICD-O-3 morphology code: 8255/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 67.7 years (24,713 days); Year of diagnosis: 2009; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes.
2. Papillary adenocarcinoma, NOS: ICD-O-3 morphology code: 8260/3; Tissue or organ of origin: Lung, NOS; Laterality: Left; Classification of tumor: Synchronous primary; AJCC staging edition: 6th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Recurrence of diagnosis 1 (Adenocarcinoma with mixed subtypes). Age at diagnosis: 71.6 years (26,163 days); Days to diagnosis: 1,450 days (4.0 years); Prior treatment: Yes.

Follow-up (4 entries)
- Day 1,450 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 1,450 days (4.0 years); Evidence of recurrence type: Biopsy with Histologic Confirmation.
- Days to follow up: 1,528 days (4.2 years); Disease response: With Tumor.
- ECOG performance status: 0; Timepoint: Preoperative.
- Follow-up contact recording only the day: day 994.

Other clinical attributes
- DLCO (% of predicted): 57; FEV1 before bronchodilator (% of reference): 100.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 94; Tobacco smoking onset year: 1955; Tobacco smoking quit year: 2002.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-78-7633-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.9; Shortest dimension: 0.5.
  Slide TCGA-78-7633-01A-01-BS1: Section location: Bottom; Percent tumor cells: 87; Percent tumor nuclei: 80; Percent normal cells: 3; Percent necrosis: 0; Percent stromal cells: 10.
  Slide TCGA-78-7633-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 75; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-78-7633-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-78-7633-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma Mixed Subtype; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tobacco smoking history indicator: 4; Anatomic organ subdivision: L-Upper; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease.
- Follow-up form 2, New neoplasm event types: New tumor event type: Locoregional Recurrence.
- Other malignancy form: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Lung; Other malignancy histological type: Lung Papillary Adenocarcinoma.

GDC annotations on this case (curator notes; quoted as recorded):
- Synchronous malignancy: Pt with synchronous L papillary adenocarcinoma.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,528 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,528 days; disease-free interval: event (new tumor event after initially disease-free), 1,450 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,450 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-78-7633-01A-11D-2062-01): tumor purity 0.75, ploidy 2.19, whole-genome doublings 0.
